Somatic mutation profile of tumor specimen 0DNYO2 from CCDI case PBBVCM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Craniopharyngioma, adamantinomatous; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,789 days).
Specimen 0DNYO2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44ca0f1d-73c5-437b-9666-ef37e87751b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNYNI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d290c85-a884-44e5-9c19-413d0641265c

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 90/740 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.452A>G p.E151G | Missense Mutation (SNP) | VAF 35/1191 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- IQCC | c.1118A>T p.E373V | Missense Mutation (SNP) | VAF 36/600 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2
- SLA | c.475C>T p.H159Y (on ENST00000338087 / NM_001045556.3; = p.H199Y on NM_006748.4) | Missense Mutation (SNP) | VAF 39/364 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
